Gene-level copy-number profile of tumor specimen HTMCP-01-06-00299-01A from CGCI case HTMCP-01-06-00299, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 32.8 years (11,988 days).
Specimen HTMCP-01-06-00299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 21072971-c2df-4612-a156-117e22cc85c9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00299-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/25aaa604-2bc8-4224-8be1-89a3a245ee45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 1,621; copy number 2: 47,637; copy number 3: 6,119; copy number 4: 2,986; copy number 5: 7; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,485,030–160,954,809, 19 genes: SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2.
- chr1:248,573,801–248,645,278, 6 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,581,339–161,678,654, 5 genes, copy number 6 (within-gene range 3–6): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B.
- chr2:12,598,987–13,331,683, 7 genes, copy number 5: AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1.

Autosomal genes at a single copy (total copy number 1): 1,621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
